Somatic mutation profile of tumor specimen C3N-03841-01 (aliquot CPT0236850007) from CPTAC case C3N-03841, project CPTAC-3 (Other and ill-defined sites — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 59.5 years (21,732 days).
Specimen C3N-03841-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Supraglottis; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9b6f3f8-cf0d-4f4a-9327-d0baaf6b44aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03841-31 (Blood Derived Normal), aliquot CPT0236910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38ed37b9-e96d-4661-89cf-d9b5a0b729bc

The open-access MAF lists 117 somatic variants for this specimen: 80 protein-altering or splice-affecting, 21 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 21, Intron 6, Splice Site 4, Frame Shift Ins 4, 3'UTR 3, Frame Shift Del 3, Nonsense Mutation 3, RNA 3, 5'Flank 2, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 211/544 reads (39%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1289G>C p.G430A | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52221469; called by muse, mutect2, varscan2
- ANAPC1 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs746068671; called by muse, mutect2, varscan2
- ARID5B | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54430384; called by muse, mutect2, varscan2
- CLDND1 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1229831603; called by muse, mutect2, varscan2
- CLSTN1 | c.839C>T p.A280V (on ENST00000377298 / NM_001009566.3; = p.A270V on NM_014944.4) | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs1245004194, COSV100790557, COSV63650002; called by muse, mutect2, varscan2
- CYP21A2 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 122/711 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM106849; called by muse, mutect2, varscan2
- DOCK7 | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51994832; called by muse, mutect2, varscan2
- DUS3L | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.072); catalogued as COSV57833232; called by muse, mutect2, varscan2
- EP300 | c.4167C>G p.N1389K | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99607134, COSV99607371; called by muse, mutect2, varscan2
- ERCC6 | c.4442G>T p.G1481V | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1465700433; called by muse, mutect2, varscan2
- GPR15 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200700815, COSV52520567; called by muse, mutect2, varscan2
- HNRNPDL | c.1202G>C p.S401T | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV55022149; called by muse, mutect2, varscan2
- INVS | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 141/394 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as rs1034701286; called by muse, mutect2, varscan2
- KCTD3 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs765491489, COSV52070030; called by muse, mutect2
- KIF9 | c.2312T>C p.I771T (on ENST00000265529 / NM_001377474.1; = p.I706T on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759969622; called by muse, mutect2, varscan2
- LRRIQ1 | c.3223G>A p.V1075I | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs146525952; called by muse, mutect2, varscan2
- MMP15 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1303414543; called by muse, mutect2, varscan2
- NAV3 | c.2848G>A p.D950N | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV104385165; called by muse, mutect2, varscan2
- OSGEP | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.068); catalogued as rs1279041523, COSV51658475; called by muse, mutect2, varscan2
- PCDHA5 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 108/802 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.15); catalogued as COSV100972067; called by muse, mutect2, varscan2
- PTPRU | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs149813959; called by muse, mutect2, varscan2
- RAD51AP2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV101208390; called by muse, mutect2
- SALL1 | c.3586C>T p.R1196W | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1361783109; called by muse, mutect2, varscan2
- SLC6A20 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543809395; called by muse, mutect2, varscan2
- VPS13B | c.7997G>A p.R2666H | Missense Mutation (SNP) | VAF 58/353 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124338, COSV62138977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WASHC4 | c.1768A>G p.I590V | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs1366043561; called by muse, mutect2, varscan2
- ZCCHC4 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs917165051; called by muse, mutect2, varscan2
- ZNF28 | c.1125G>T p.R375S | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs749189485; called by muse, mutect2, varscan2
- ZNF587 | c.1603C>G p.L535V | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV57147147; called by muse, mutect2, varscan2
- ADCK5 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ADRA1D | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 209/498 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AMHR2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 219/635 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF18 | c.1002C>G p.N334K (on ENST00000359920 / NM_001130955.2; = p.N230K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ASXL1 | c.1981dup p.R661Kfs*7 | Frame Shift Ins (INS) | VAF 58/171 reads (34%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.2567_2572+17del p.X856_splice | Splice Site (DEL) | VAF 38/132 reads (29%) | called by mutect2, pindel
- CACNA1I | c.6324G>C p.E2108D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); called by muse, mutect2
- CCDC27 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CDON | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 135/429 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CHMP3 | c.295_298del p.R99Wfs*11 | Frame Shift Del (DEL) | VAF 50/160 reads (31%) | called by mutect2, pindel, varscan2
- CHRNB3 | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRK | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by mutect2, varscan2
- CWF19L2 | c.1228A>G p.K410E | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- F2 | c.1640_1642del p.N547del | In Frame Del (DEL) | VAF 22/128 reads (17%) | called by pindel, varscan2
- FAM135B | c.402C>A p.S134R | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXL17 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- FMO1 | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FOXO1 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GARRE1 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 88/661 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- GPS2 | c.651dup p.A218Cfs*43 | Frame Shift Ins (INS) | VAF 74/240 reads (31%) | called by mutect2, pindel, varscan2
- HSPH1 | c.2353A>G p.I785V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ID4 | c.245_246insTTT p.I82_P83insF | In Frame Ins (INS) | VAF 97/312 reads (31%) | called by mutect2, pindel, varscan2
- ILF3 | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.205); called by mutect2, varscan2
- NBPF12 | c.989-2A>C p.X330_splice | Splice Site (SNP) | VAF 93/803 reads (12%) | called by muse, mutect2, varscan2
- NKD1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 21/195 reads (11%) | called by muse, mutect2, varscan2
- NRXN1 | c.1521T>A p.D507E | Missense Mutation (SNP) | VAF 151/423 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OTOL1 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 392/610 reads (64%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PARD3 | c.3311A>T p.Y1104F | Missense Mutation (SNP) | VAF 62/484 reads (13%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.986); called by muse, varscan2
- PARD3 | c.3310T>A p.Y1104N | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, varscan2
- PARP14 | c.2282A>T p.Y761F | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCLO | c.2980A>G p.I994V | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDIA5 | c.1520del p.G507Efs*6 | Frame Shift Del (DEL) | VAF 74/308 reads (24%) | called by pindel, varscan2
- PEAK3 | c.632_642del p.D211Afs*25 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.4247G>A p.S1416N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PIK3R4 | c.3709-1G>A p.X1237_splice | Splice Site (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- RAB26 | c.689dup p.M230Ifs*13 | Frame Shift Ins (INS) | VAF 48/333 reads (14%) | called by mutect2, pindel, varscan2
- RBM12 | c.1391A>T p.Y464F | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RBX1 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- RTKN | c.1058A>T p.E353V (on ENST00000272430 / NM_001015055.2; = p.E340V on NM_033046.2) | Missense Mutation (SNP) | VAF 150/353 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- SLC35A5 | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPHKAP | c.4477G>C p.E1493Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.446); called by muse, varscan2
- SPRYD4 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- SPTBN2 | c.6751dup p.R2251Pfs*38 | Frame Shift Ins (INS) | VAF 122/450 reads (27%) | called by mutect2, pindel, varscan2
- STARD3NL | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TRAT1 | c.312T>G p.N104K | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VEGFB | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 87/660 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- ZC3H4 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2
- ZDHHC19 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 89/477 reads (19%) | called by muse, mutect2, varscan2
- ZNF28 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ZNF792 | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ADRB1 | c.528G>T p.R176= | Silent (SNP) | VAF 110/558 reads (20%) | called by muse, mutect2, varscan2
- ALPK1 | c.492A>G p.A164= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- CACNG7 | c.621G>A p.E207= | Silent (SNP) | VAF 43/279 reads (15%) | called by muse, mutect2, varscan2
- CDON | c.1357C>T p.L453= | Silent (SNP) | VAF 139/430 reads (32%) | called by muse, mutect2, varscan2
- CYP21A2 | c.1377G>A p.L459= | Silent (SNP) | VAF 123/714 reads (17%) | called by muse, mutect2, varscan2
- DAOA | c.153A>C p.G51= | Silent (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- DHCR7 | c.1021C>T p.L341= | Silent (SNP) | VAF 25/455 reads (5%) | called by muse, mutect2
- GPR137B | c.66C>T p.D22= | Silent (SNP) | VAF 33/232 reads (14%) | catalogued as rs1430218427; called by muse, mutect2, varscan2
- HES2 | c.33G>C p.A11= | Silent (SNP) | VAF 97/320 reads (30%) | called by muse, mutect2, varscan2
- KDM4A | c.3102G>A p.E1034= | Silent (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- LMF1 | c.450C>T p.L150= | Silent (SNP) | VAF 83/517 reads (16%) | catalogued as COSV51902011; called by muse, mutect2, varscan2
- MSTO1 | c.33G>A p.L11= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, varscan2
- PCDHB4 | c.1641C>T p.R547= | Silent (SNP) | VAF 99/887 reads (11%) | catalogued as rs377522159; called by muse, mutect2, varscan2
- PCDHGB7 | c.21G>A p.Q7= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV53903814; called by muse, varscan2
- PSCA | c.210G>T p.V70= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV100008285; called by muse, mutect2, varscan2
- RFXAP | c.612T>C p.D204= | Silent (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- SDK1 | c.6327G>A p.V2109= | Silent (SNP) | VAF 106/285 reads (37%) | called by muse, mutect2, varscan2
- TMEM80 | c.570G>A p.L190= | Silent (SNP) | VAF 119/707 reads (17%) | called by muse, mutect2, varscan2
- TSPYL1 | c.538C>T p.L180= | Silent (SNP) | VAF 120/723 reads (17%) | catalogued as rs1390984858; called by muse, mutect2, varscan2
- TTN | c.15735G>A p.Q5245= (on ENST00000591111; = p.Q4318= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- ZNF583 | c.1008T>G p.G336= | Silent (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503969 A>G | 5'Flank (SNP) | VAF 5/40 reads (13%) | catalogued as rs760095632; called by muse, mutect2, varscan2
- BMP1 | c.2107+1773G>A | Intron (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- CEP170 | c.274+42A>T | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- CHD1 | c.4428-136A>G | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812075 G>T | 3'Flank (SNP) | VAF 8/245 reads (3%) | called by muse, mutect2
- COPS2 | c.372+29G>A | Intron (SNP) | VAF 5/47 reads (11%) | catalogued as rs369173476; called by mutect2, varscan2
- GTF2IRD2P1 | chr7:73269291 C>A | 5'Flank (SNP) | VAF 66/958 reads (7%) | called by muse, mutect2
- HUWE1 | c.-17A>G | 5'UTR (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- JPH3 | c.2167-621G>C | Intron (SNP) | VAF 206/454 reads (45%) | called by muse, mutect2, varscan2
- MIR520D | n.48G>A | RNA (SNP) | VAF 72/261 reads (28%) | called by muse, mutect2, varscan2
- MYO15B | c.7774-109T>C | Intron (SNP) | VAF 60/390 reads (15%) | called by muse, mutect2, varscan2
- NCF1B | n.336C>T | RNA (SNP) | VAF 48/339 reads (14%) | catalogued as rs201373712; called by mutect2, varscan2
- NFU1 | c.*52A>G | 3'UTR (SNP) | VAF 43/88 reads (49%) | catalogued as COSV100361367; called by muse, mutect2, varscan2
- RAB35 | c.*109C>T | 3'UTR (SNP) | VAF 63/234 reads (27%) | catalogued as COSV57494551; called by muse, mutect2, varscan2
- TLX1NB | n.1515C>T | RNA (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2116A>G | 3'UTR (SNP) | VAF 12/126 reads (10%) | catalogued as rs1187673402; called by muse, mutect2
